Surgical pathology report (de-identified scan), TCGA case TCGA-94-A5I4, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-A5I4-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

* Final Report *

Document Type: Anat Path Reports

Document Date:

Document Status:

Document Title:

Performed By:

Verified By:

Encounter info:

* Final Report *

ICD-0-3
Carcinoma, squamous cell NOS
8070/3
Site (R) Lung, main bronchus
234.0
9/25/13

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender: M

Acc #:

Pulmonary Big

Collected

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LYMPH NODE, RIGHT LEVEL 7, BIOPSY, A1FS-A5FS:
-MULTIPLE LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA (0/9).
- B. LYMPH NODE, 4R, BIOPSY, B1FS-8FS:
-MULTIPLE LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA (0/18).
- C. LYMPH NODE, LEVEL 9R, BIOPSY:
-MULTIPLE LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA (0/2).
- D. LUNG, RIGHT, PNEUMONECTOMY, D1FS:
-SQUAMOUS CELL CARCINOMA, MODERATELY-DIFFERENTIATED, WITH NECROSIS, 4.5 CM.
-BRONCHIAL AND VASCULAR RESECTION MARGINS ARE NEGATIVE FOR TUMOR.
-VISCERAL PLEURA UNINVOLVED BY TUMOR.
-ONE OF FOUR LYMPH NODES WITH METASTATIC CARCINOMA (1/4).

Printed by:

Printed on:

[page 2 of 5]
Anat Path Reports

* Final Report *

- LYMPHOVASCULAR INVASION IS IDENTIFIED.
- UNINVOLVED LUNG PARENCHYMA WITH EMPHYSEMATOUS CHANGES.
- SEE SYNOPTIC REPORT.

Synoptic Worksheet

D. Right lung, check bronchial margins:

Specimen:	Lung
Procedure:	Pneumonectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Other: Centered around main bronchus
Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G2: Moderately differentiated
Tumor Size:	Greatest dimension: 4.5 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Tumor involves main bronchus 2 cm or more distal to the carina
Bronchial Margin:	Uninvolved by invasive carcinoma
	Squamous cell carcinoma in situ (CIS) not identified at bronchial margin
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 12 mm
	Margin closest to invasive carcinoma:: bronchial
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve

[page 3 of 5]
Anat Path Reports

* Final Report *

Regional Lymph Nodes (pN):	th the entire lung pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension Nodes involved: 1 Number of nodes examined cannot be determined
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Squamous dysplasia Emphysema

Clinical History

Lung mass. Right thoracotomy.

Specimen(s) Received

A: Level 7 lymph node (right)
B: 4R lymph node
C: Level 9R lymph node
D: Right lung, check bronchial margins

Gross Description

Three specimens are received fresh, labeled with the patient's name, and medical record number.

Specimen A is received for intraoperative consultation and is labeled "level 7 lymph node." It consists of multiple lymph node fragments and soft tissue measuring in aggregate 5.5 x 3.2 x 1.1 cm. The lymph nodes are submitted entirely for frozen section diagnosis in cassette "A1FS" through "A5FS."

Specimen B is received for intraoperative consultation and is labeled "level 4R lymph node." It consists of multiple lymph nodes and lymph node fragments measuring in aggregate 6.0 x 4.2 x 1.0 cm. The lymph nodes and lymph node fragments are submitted entirely for frozen section diagnosis in cassettes "B1FS" through "B8FS." The remaining tissue fragments are submitted in cassettes "B9" and "B10."

Specimen C is further designated "left 9R lymph node." It consists of two fragments of tan soft tissue in aggregate measuring 1.2 x 0.5 x 0.5 cm. The specimen is submitted entirely in cassette "C1."

Specimen D is further designated "right lung." It consists of a lung measuring 23.0 x 23.0 x 6.0 cm and weighing 726 grams. There is a well-circumscribed, homogenous, white mass centered around the main bronchus that invades the bronchus and approaches the peripheral edge by 3.0 cm. The mass measures 4.5 x 4.0 x 3.5 cm and is 1.2 cm from the bronchial margin. The distal central airway has abundant mucous with diffuse bronchiectasis in the surrounding parenchyma. The uninvolved parenchyma is otherwise grossly unremarkable. No hilar lymph nodes are grossly identified. A portion of tumor and normal tissue are submitted for Tissue Procurement Services. The bronchial margin is submitted for frozen section diagnosis in cassette "D1FS." Additional representative sections are submitted as follows:

CASSETTE SUMMARY:

Printed by:
Printed on:

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

A1FS: Two lymph nodes, submitted whole
A2FS: One lymph node, bisected
A3FS-AF5S: Represents multiple lymph node fragments
B1FS: Three lymph nodes, whole
B2FS: One lymph node, bisected
B3FS: Three lymph nodes, submitted whole
B4FS: Four lymph nodes, submitted whole
B5FS: Two lymph nodes, submitted whole
B6FS: Three lymph nodes, submitted whole
B7FS: One lymph node, bisected
B8FS: Multiple lymph node fragments
B9,10: Represents remaining soft tissue fragments
D2: Vascular margin, shaved
D3,D4: Mass with respect to bronchial edge, perpendicular and en face, bisected (lower lobe bronchus)
D5: Mass with respect to the positive lymph node at main bronchus bifurcation
D6: Mass with respect to pleura
D7: Mass with respect to uninvolved parenchyma
D8: Two possible peribronchial lymph nodes
D9: Mass with respect to distal plugged airway
D10: Representative uninvolved upper lobe
D11: Representative uninvolved lower lobe

Intraoperative Consult Diagnosis

A1FS-AF5S: LEVEL 7 LYMPH NODE (FROZEN SECTION): FIVE BENIGN LYMPH NODES (0/5). FRAGMENTED
BENIGN

LYMPH NODE.

Frozen section results were communicated to the surgical team and were repeated back by
The frozen section start time not provided.

B1FS-B8FS: 4R LYMPH NODE (FROZEN SECTION): EIGHTEEN BENIGN LYMPH NODES (0/18).
Frozen section results were communicated to the surgical team and were repeated back by

D1FS: RIGHT, LUNG, BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE.
Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited. regarding

Anat Path Reports

* Final Report *

Printed by:
Printed on:

Page 5 of 5
(End of Report)

Source: NCI Genomic Data Commons file edc09f16-14de-49b2-8064-1e46dfce3304 (TCGA-94-A5I4.8C32CD4E-3F9E-43E8-8E18-739561B9DA78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).